Somatic mutation profile of tumor specimen 0DGQC2 from CCDI case PBBTSD, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 11.3 years (4,142 days).
Specimen 0DGQC2: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 650689f2-7406-4e08-a404-33f718ad4d3e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DGQAG (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8afeac9b-1a85-4a2b-b46e-0cabf052abf0

The open-access MAF lists 47 somatic variants for this specimen: 27 protein-altering or splice-affecting, 8 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 8, Intron 5, 3'UTR 3, 5'UTR 3, Nonsense Mutation 3, Splice Site 2, 5'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-3A | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 704/1179 reads (60%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); catalogued as rs1057519903, COSV64731746, COSV64731769; ClinVar: likely pathogenic; called by muse, varscan2
- TP53 | c.535C>T p.H179Y | Missense Mutation (SNP) | VAF 772/826 reads (93%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs587780070, CM067054, COSV52662617, COSV52668276, COSV52699993; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- APOB | c.2064C>G p.I688M | Missense Mutation (SNP) | VAF 115/606 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as rs774188993, COSV99267195; called by muse, mutect2, varscan2
- CROCC2 | c.2966C>T p.T989M | Missense Mutation (SNP) | VAF 289/1281 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.023); catalogued as rs895743062; called by muse, mutect2, varscan2
- EFNB2 | c.955C>T p.Q319* | Nonsense Mutation (SNP) | VAF 1016/1617 reads (63%) | catalogued as COSV55367573; called by muse, mutect2, varscan2
- GAL3ST3 | c.863G>A p.R288H | Missense Mutation (SNP) | VAF 327/708 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs745551285, COSV61749016, COSV61749254; called by muse, varscan2
- LAMA5 | c.2984C>G p.T995S | Missense Mutation (SNP) | VAF 42/1608 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs935852351; called by muse, mutect2
- PRR35 | c.941G>A p.R314Q | Missense Mutation (SNP) | VAF 30/204 reads (15%) | SIFT tolerated (0.52); PolyPhen benign (0.005); catalogued as rs755583168; called by muse, mutect2, varscan2
- SLAMF7 | c.550T>A p.W184R | Missense Mutation (SNP) | VAF 62/1130 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs141021747; called by muse, mutect2
- ST7 | c.1338C>A p.F446L (on ENST00000265437 / NM_021908.3; = p.F423L on NM_018412.4) | Missense Mutation (SNP) | VAF 353/1198 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55382433; called by muse, mutect2, varscan2
- BLZF1 | c.955C>G p.Q319E | Missense Mutation (SNP) | VAF 209/1656 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 64/1465 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- CACNG6 | c.233C>T p.A78V | Missense Mutation (SNP) | VAF 96/484 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CEP350 | c.3947G>T p.G1316V | Missense Mutation (SNP) | VAF 120/696 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); called by mutect2, varscan2
- CNDP2 | c.1331C>A p.A444D | Missense Mutation (SNP) | VAF 81/670 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- FGD6 | c.1346G>A p.C449Y | Missense Mutation (SNP) | VAF 151/583 reads (26%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- FSTL3 | c.788T>C p.V263A | Missense Mutation (SNP) | VAF 342/781 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.332); called by muse, mutect2, varscan2
- HCFC2 | c.375T>A p.C125* | Nonsense Mutation (SNP) | VAF 232/813 reads (29%) | called by muse, varscan2
- HTR5A | c.800C>G p.T267S | Missense Mutation (SNP) | VAF 142/1221 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- KASH5 | c.1252G>T p.A418S | Missense Mutation (SNP) | VAF 115/1621 reads (7%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.003); called by muse, mutect2
- LTBP4 | c.2902C>T p.R968* (on ENST00000308370 / NM_001042544.1; = p.R931* on NM_003573.2) | Nonsense Mutation (SNP) | VAF 116/666 reads (17%) | called by muse, mutect2, varscan2
- NWD1 | c.3592del p.D1198Ifs*87 | Frame Shift Del (DEL) | VAF 90/519 reads (17%) | called by mutect2, varscan2
- OR4A5 | c.919A>T p.I307F | Missense Mutation (SNP) | VAF 92/413 reads (22%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- PALM2AKAP2 | c.2302+1G>A p.X768_splice (on ENST00000259318 / NM_001136562.3; = p.X999_splice on NM_007203.5) | Splice Site (SNP) | VAF 71/360 reads (20%) | called by muse, mutect2, varscan2
- RAD51C | c.706-1G>A p.X236_splice | Splice Site (SNP) | VAF 147/544 reads (27%) | called by muse, mutect2, varscan2
- RBKS | c.857C>A p.S286Y | Missense Mutation (SNP) | VAF 226/1050 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); called by muse, mutect2, varscan2
- SUN2 | c.1352A>G p.D451G | Missense Mutation (SNP) | VAF 224/832 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ANK2 | c.1422C>T p.A474= | Silent (SNP) | VAF 216/572 reads (38%) | catalogued as rs151180821; ClinVar: likely benign; called by muse, mutect2, varscan2
- ANKIB1 | c.642T>A p.A214= | Silent (SNP) | VAF 72/1052 reads (7%) | called by muse, mutect2
- ATP6V0A1 | c.207G>A p.E69= | Silent (SNP) | VAF 112/1098 reads (10%) | called by muse, mutect2
- CLEC4M | c.27G>A p.V9= | Silent (SNP) | VAF 93/1054 reads (9%) | called by muse, mutect2
- DOT1L | c.1260G>A p.A420= | Silent (SNP) | VAF 344/725 reads (47%) | catalogued as rs574510793, COSV67109425; called by muse, mutect2, varscan2
- INTS12 | c.852G>A p.S284= | Silent (SNP) | VAF 533/619 reads (86%) | catalogued as rs141555014, COSV60863132; called by muse, mutect2, varscan2
- OPRM1 | c.339T>C p.A113= | Silent (SNP) | VAF 30/1239 reads (2%) | called by muse, mutect2
- OR1N1 | c.816A>T p.A272= | Silent (SNP) | VAF 16/309 reads (5%) | called by muse, mutect2
- ACAA1 | c.-13G>A | 5'UTR (SNP) | VAF 104/386 reads (27%) | called by muse, mutect2, varscan2
- CCDC149 | c.63+17714C>A | Intron (SNP) | VAF 26/794 reads (3%) | catalogued as rs1341369251; called by muse, mutect2
- CCDC149 | c.63+17713T>G | Intron (SNP) | VAF 26/758 reads (3%) | called by muse, mutect2
- DPYSL5 | c.*37C>A | 3'UTR (SNP) | VAF 140/458 reads (31%) | called by muse, mutect2, varscan2
- EEF1AKMT2 | c.292-25A>T | Intron (SNP) | VAF 14/144 reads (10%) | called by muse, varscan2
- IPO5 | c.-138A>T | 5'UTR (SNP) | VAF 49/225 reads (22%) | called by muse, mutect2, varscan2
- MAMDC2 | c.1651+5248C>T | Intron (SNP) | VAF 80/377 reads (21%) | catalogued as rs993792875; called by muse, mutect2, varscan2
- OR2L2 | c.*23A>C | 3'UTR (SNP) | VAF 143/724 reads (20%) | catalogued as COSV63552727; called by muse, mutect2, varscan2
- PDZRN4 | c.*71G>A | 3'UTR (SNP) | VAF 10/59 reads (17%) | called by muse, mutect2, varscan2
- SECISBP2 | c.-17C>T | 5'UTR (SNP) | VAF 57/491 reads (12%) | catalogued as rs970643926; called by muse, mutect2, varscan2
- SENP6 | c.2288+11A>T | Intron (SNP) | VAF 24/863 reads (3%) | called by muse, mutect2
- SUCO | chr1:172532743 G>A | 5'Flank (SNP) | VAF 318/2059 reads (15%) | catalogued as rs1262538084; called by muse, mutect2, varscan2
